Somatic mutation profile of tumor specimen TARGET-15-SJMPAL016343-09A.3 (aliquot TARGET-15-SJMPAL016343-09A.3-01D) from TARGET case TARGET-15-SJMPAL016343, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,198 days).
Specimen TARGET-15-SJMPAL016343-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a2cab72-ba37-4b06-804e-916c38c917bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL016343-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL016343-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15b10f0d-bd7e-43df-a913-e0b4969a2c22

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGF1 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV61032415; called by muse, mutect2
- SPTY2D1 | c.1550G>T p.S517I | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2
- RIPK1 | c.480C>A p.A160= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
